Surgical pathology report (de-identified scan), TCGA case TCGA-E3-A3DZ, project TCGA-THCA (Thyroid Carcinoma), tissue source site Roswell Park, specimen TCGA-E3-A3DZ-01A (Primary Tumor).

Surgery Date

SPECIMENS:

A. TOTAL THYROID

SPECIMEN(S):

A. TOTAL THYROID

DIAGNOSIS:

- A. THYROID, THYROIDECTOMY:
- PAPILLARY CARCINOMA, FOLLICULAR VARIANT, PRESENT IN THE RIGHT LOBE, MEASURING 5 CM
- SURGICAL RESECTION MARGINS NEGATIVE FOR TUMOR
- PARATHYROID GLAND WITH NO SPECIFIC PATHOLOGIC CHANGES
- ONE LYMPH NODE, NEGATIVE FOR METASTASES (0/1)
- SQUAMOUS METAPLASIA (LEFT LOBE)
- SEE SYNOPTIC REPORT AND SEE NOTE.

NOTE: Dr. concurs.

SYNOPTIC REPORT - THYROID GLAND

Specimen Type: Total thyroidectomy
Tumor Site: Right lobe
Tumor Focality: Multifocal
Tumor Size (largest nodule): Greatest dimension: 5cm
WHO CLASSIFICATION
Papillary carcinoma, variant 8260/3
Follicular variant
Margins: Margins uninvolved by carcinoma
Vascular Invasion: Absent
Additional Pathologic Findings: None identified
Lymph Node: Not performed
Pathological Staging (pTNM): pT 3 N 0 M x
Pathological staging is based on the AJCC Cancer Staging Manual, 7th Edition

GROSS DESCRIPTION:

A. TOTAL THYROID

Received fresh labeled with the patient's identification and 'total thyroid' is an oriented tan pink, intact total thyroidectomy specimen. The left lobe is 5.2 x 2.3 x 1.4cm, the isthmus is 1.3 x 1.2cm and the right lobe is 6.5 x 5.6 x 3cm. The anterior aspect of the specimen is inked blue. The posterior aspect is inked black. The left lobe is serially sectioned from superior to inferior to reveal multiple mucinous nodules, the largest of which is 0.9cm, located in the inferior pole. The isthmus is serially sectioned from left to right to reveal unremarkable parenchyma. The right lobe is serially sectioned from superior to inferior to reveal a 4.5 x 5 x 3cm encapsulated mass located in the upper and middle lobe. The remaining parenchyma is red-brown. A portion of the specimen is submitted for tissue procurement. Entirely submitted:

- A1-A6: left lobe
A7: isthmus
A8-A20: right lobe

CLINICAL HISTORY:

None provided.

PRE-OPERATIVE DIAGNOSIS:

Multinodular goiter.

Gross Dictation: , ,
Final Review: , M.D., Pathologist. ,
Final: , M.D., Pathologist,

1CD-0-3
carcinoma, papillary, follicular variant 8340/3
Site: thyroid, NOS C73.9 lw
10/26/11

Source: NCI Genomic Data Commons file 0696418e-b396-4c5b-a4b4-ae0d1c6b11d4 (TCGA-E3-A3DZ.B9BD9C12-4F77-4B8F-9C8E-316CA441FC6A.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).